Gene-level copy-number profile of tumor specimen C3N-01366-02 from CPTAC case C3N-01366, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.3 years (23,121 days).
Specimen C3N-01366-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f4f7b57c-8e55-456f-a3bf-ffbca068b4d3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01366-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/170533b5-dd5d-446a-a31d-82829ac15d23

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 5,523; copy number 2: 47,211; copy number 3: 4,031; copy number 4: 1,999; copy number 5: 44; copy number 7: 1; copy number 8: 4; copy number 12: 1; copy number 16: 1; copy number 20: 7; copy number 30: 1; copy number 42: 18; copy number 43: 5.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–22,128,103, 64 genes (broad region; genes not listed).
- chr9:129,110,950–129,148,946, 1 gene (within-gene range 0–1): PTPA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 82 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:52,891,837–56,381,312, 78 genes, copy number 5–43 (broad region; genes not listed).
- chr10:43,323,665–43,376,335, 4 genes, copy number 8: LINC02633, AC068707.1, RNU6ATAC11P, FXYD4.

Autosomal genes at a single copy (total copy number 1): 2,672. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
